Gene-level copy-number profile of tumor specimen TCGA-55-6968-01A from TCGA case TCGA-55-6968, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-55-6968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8fac7059-d7b3-4043-a7cb-0968cf8b540e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6968-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80761f5c-9a49-414e-ba78-adbcbff097b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22,152; copy number 2: 35,225; copy number 3: 2,271; copy number 4: 123; copy number 5: 35; copy number 6: 2; copy number 8: 3; copy number 10: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6968-01A-11D-1943-01): tumor purity 0.65, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,456,480–1,551,710, 3 genes, copy number 8: LPCAT1, MIR6075, AC091849.2.
- chr5:7,396,138–8,014,804, 8 genes, copy number 10 (within-gene range 1–10): ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1.
- chr6:75,454,944–76,092,940, 17 genes, copy number 5–6: AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P.
- chr18:14,946,267–15,330,282, 16 genes, copy number 5: LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:30,290,161–30,780,424, 4 genes, copy number 5: AC115100.1, MIR302F, AC090506.1, AC090506.2.

Autosomal genes at a single copy (total copy number 1): 19,739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
